MMRF case MMRF_1662 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4a4710d1-40eb-4365-b733-358b36eea26e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.3 years (28,583 days); ISS stage: II; Days to last known disease status: 1,199 days (3.3 years); Days to last follow up: 1,199 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 398 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 192 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 399 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1: M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Albumin 22 g/L; Total Protein 4.1 g/dL; Glucose 4.62 mmol/L; C-Reactive Protein 0 mg/dL.
- Day 98: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 7.75 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 4.84 mmol/L.
- Day 168: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 4.84 mmol/L.
- Day 274: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 9 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 356: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 2.98 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 497: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.04 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 3.48 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 4.53 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 533: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 3.63 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 231 ×10⁹/L.
- Day 615 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 2.91 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.
- Day 720 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 3.1 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.68 mmol/L.
- Day 874: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.39 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 3.46 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 4.29 mmol/L.
- Day 930 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.66 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 3.21 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 1,015 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 5.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 3.83 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.
- Day 1,080 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 8.49 g/L; Immunoglobulin A 2.8 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 4.35 mmol/L.
- Day 1,199 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 9.75 g/L; Immunoglobulin A 3.12 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -1: Weight: 99 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1662_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1662_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
